Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A7JC, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A7JC-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, squamous cell
NOS 8070/3
Site Floor of mouth NOS
C04.9
JW 9/24/13

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Floor of mouth

1-"Left - Level IIA lymph node":

. 5 lymph nodes were dissected, all uninvolved by neoplasia (0/5).

2-"Right - Level IIB lymph node":

. 1 of 10 lymph nodes involved by metastatic squamous cell carcinoma (1/10), without capsular involvement.

3-"Left - Level IB lymph node":

. 2 lymph nodes were dissected, all uninvolved by carcinoma (0/2).
. Salivary gland uninvolved by neoplasia.

4-"Left - Level III lymph node":

. 6 lymph nodes were dissected, all uninvolved by neoplasia (0/6).

5-"Right - Level III lymph node":

. 2 lymph nodes were dissected, all uninvolved by neoplasia (0/2).

6-"Right - Level IIA lymph node":

. 2 of 10 lymph nodes involved by metastatic squamous cell carcinoma (2/10), with capsular involvement, without formation of conglomerates.
. Salivary gland uninvolved by neoplasia.

7-"Level IA lymph node":

. 2 lymph nodes were dissected, all uninvolved by neoplasia (0/2).

8-"Right - Level IB lymph node":

. 2 lymph nodes were dissected, all uninvolved by neoplasia (0/2).
. Salivary gland uninvolved by neoplasia.

9-"Pelvi-Glosso-Mandibulectomy":

. Invasive well differentiated squamous cell carcinoma.
. Tumor size: 6.0 cm (greatest dimension) and 4.0 cm deep.
. Lymphatic invasion: present.
. Perineural invasion: not detected.
. Anterior mucous margin involved by neoplasia.

[page 2 of 2]
. Other mucous margins uninvolved by neoplasia.

10-"Marginal central mandibulectomy":

. Osseous tissue uninvolved by neoplasia.

Print Malignancy History		✓

Source: NCI Genomic Data Commons file 22173cd4-77d0-4bad-8dc1-778f9afebb4a (TCGA-UF-A7JC.A14616B6-125E-4095-9046-98FEE6C0F406.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).